Surgical pathology report (de-identified scan), TCGA case TCGA-16-1460, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Toronto Western Hospital, specimen TCGA-16-1460-01A (Primary Tumor).

[page 1 of 2]
16-1460

Patient Name: [REDACTED]
MRN: [REDACTED]
Gender: F
HCN: [REDACTED]
Ordering MD: [REDACTED]

Service: [REDACTED]
Visit #: [REDACTED]
Location: [REDACTED]
Facility: [REDACTED]

Copath #: [REDACTED]
Collected: [REDACTED]
Resulted: [REDACTED]

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

- 1. BRN: Left brain tumour
- 2. BRN: Left brain tumour for quick section

DIAGNOSIS

- 1. and 2. Brain, left brain tumor:
- Glioblastoma, WHO grade IV (see microscopic description)

SYNOPTIC DATA

----- MACROSCOPIC -----
Specimen Type: Subtotal/partial resection
Specimen Size: Greatest dimension: 2.3 cm
Tumor Site: Cerebrum (specify lobe(s), if known): left frontal
Tumor Size: Largest dimension: 5 cm
----- MICROSCOPIC -----
Histologic Type: Glioblastoma
Histologic Grade: WHO Grade IV
Margins: Not applicable
Additional Studies: None performed

CLINICAL HISTORY

[REDACTED] who presented with [REDACTED] and [REDACTED]
[REDACTED] CT performed in [REDACTED] at that time showed a large calcified

[page 2 of 2]
16-1460

Patient Name: [REDACTED]

MRN: [REDACTED]

Gender: F

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: [REDACTED]

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

cystic frontal lesion. An incomplete resection was performed in [REDACTED]
[REDACTED]. Patient moved to [REDACTED] now has [REDACTED]

GROSS DESCRIPTION

1. The specimen container labeled with the patient's name and as "brain: Left brain tumor", contains multiple pieces of white tissue measuring up to 2.3 x 1.8 x 1.2 cm in maximal dimension received in 10% buffered formalin. The total weight is 14 g.

1A-1C the largest piece transected and submitted in total

1D the second largest piece bisected and submitted in toto

1E-1I remainder specimen submitted in toto

2. The specimen container labeled with the patient's name and as "brain: Left brain tumor", contains one piece of soft tan tissue measuring 0.8 x 0.8 x 0.4 cm in maximal dimension received in fresh. The tissue is bisected and one half is examined at the intra-operative consultation by frozen section. Tissue is submitted in total as follows:

2A frozen section resubmitted

2 B remained the specimen

[REDACTED]
2. Left brain tumor:

- high-grade astrocytoma with focal vascular proliferation

MICROSCOPIC DESCRIPTION

Sections demonstrate a cellular high-grade glioma with gemistocytic morphology and frequent small glomeruloid vascular proliferations. No areas of necrosis are seen. Tumor cells display pleomorphic nuclei and have abundant eosinophilic cytoplasm. Mitotic activity is present. Some fragments, especially from the CUSA specimen (slides 1E-I) show abundant calcifications, suggesting that the tumor may have arisen from a lower-grade lesion. In conclusion, the findings are those of a glioblastoma, WHO grade IV.

Source: NCI Genomic Data Commons file 918e33f2-7a45-436a-82c7-ddddb79ce5dc (TCGA-16-1460.15D0B521-884D-4AD3-8928-6F27E9D3F701.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).